Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4748, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4748-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:
Obstructing transverse colon mass with biopsy consistent with
adenocarcinoma.

Specimens Submitted:
1: COLON, TRANSVERSE; RESECTION

DIAGNOSIS:

1. COLON, TRANSVERSE; RESECTION:
- TUMOR TYPE: MUCINOUS (COLLOID) ADENOCARCINOMA (GREATER THAN 50% MUCINOUS COMPONENT).
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: TRANSVERSE COLON.
- TUMOR SIZE: LENGTH IS 4.5 CM; WIDTH IS 7 CM, MAXIMAL THICKNESS IS 2 CM.
- GROSS CONFIGURATION: ULCERATING INFILTRATIVE.
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): IDENTIFIED, OF ADENOMA TYPE.
- TUMOR INVASION: INVASION INTO SUBSEROZA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROHAL INVOLVEMENT: IDENTIFIED.
- VASCULAR INVASION: IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS: FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS [REDACTED] pT4.
- LYMPH NODES: NUMBER WITH METASTASES: 1; NUMBER EXAMINED: 23.
- THREE MESENTERIC TUMOR DEPOSITS ARE PRESENT.
- THE PATHOLOGIC STAGE IS [REDACTED]: pN1.
- IMMUNOHISTOCHEMICAL STAINS FOR DNA MISMATCH REPAIR PROTEINS SHOW THE STAINING FOR MLH1, MSH2, MSH6 AND PMS2 IS PRESENT IN THE TUMOR/

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified

** Continued on next page **

[page 2 of 3]
qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received in formalin labeled "transverse colon, stitch marks distal" and consists of a 23 cm in length by 8 cm in circumference portion of bowel with a stitch marking the distal end. The serosa is tan-brown and smooth with up to 17 cm of attached yellow-tan, lobulated fibroadipose tissue. Opening of the colon reveals a 4.5 cm length by 7 cm in diameter, tan-pink, lobular, focally mucoid, centrally ulcerated lesion. Sectioning reveals firm, mucinous cut surfaces with diffuse invasion through the serosa and into the underlying fat. The depth of invasion is up to 2 cm, with a 1.5 x 1.5 cm satellite tumor focus in the attached fat, approximately 5 cm away. The remainder of the mucosa is tan-brown and normally rugated. A portion of the specimen is sent for TPS. The specimen is sent for lymph node dissection and all identifiable lymph nodes are submitted. Representative sections are submitted.

Summary of sections:

PM proximal margin
DM distal margin
T tumor
TI tumor with deepest invasion
RS representative sections of uninvolved mucosa
LN lymph nodes
BLN bisected lymph nodes
ADD satellite tumor focus

Summary of Sections:

Part 1: COLON, TRANSVERSE; RESECTION

Block	Sect.	Site	PCs
1		ADD	1
2		DM	2
8		LN	24
2		PM	2
2		RS	4

** Continued on next page **

[page 3 of 3]
5
1

T
TY

5
1

Page 3 of 3

Addendum Diagnosis

THE IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR PROTEINS
(MLH1, MSH2, MSH6 AND PMS2) IS RETAINED IN THE TUMOR.

** End of Report **

Source: NCI Genomic Data Commons file a54f5510-64b6-44bd-9f3f-1c0935570c50 (TCGA-CM-4748.D86E67B0-5A10-4760-A2F8-420A06C83DE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).